TCGA case TCGA-08-0375 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0ce23e2c-8e64-4391-8148-de823bce0d5f

Demographics
Sex at birth: female; Age at index: 51 years; Vital status: Dead; Days to death: 372 days (1.0 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 51.9 years (18,941 days); Year of diagnosis: 1994; Method of diagnosis: Excisional Biopsy; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 41 days; Days to treatment end: 83 days; Treatment dose: 5,940 mCi; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 181 days; Days to treatment end: 181 days; Treatment dose: 3,500 cGy; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 52.3 years (19,102 days); Days to diagnosis: 161 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 161 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 161 days.
- Days to follow up: 279 days; Disease response: With Tumor.
- Days to follow up: 372 days (1.0 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0375-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.4; Intermediate dimension: 0.3; Shortest dimension: 0.3.
  Slide TCGA-08-0375-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
  Slide TCGA-08-0375-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
- Sample TCGA-08-0375-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0375-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: Yes; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Radiation treatment 1: Radiation type other: 2 knife; Therapy regimen: Progression.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: Per enrollment form, patient had a prior diagnosis of a lower grade glioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 372 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 372 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 161 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0375-01): tumor purity 0.89, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).
